Gene-level copy-number profile of tumor specimen MP2PRT-PARTAH-TMP1-B from MP2PRT case MP2PRT-PARTAH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,330 days).
Specimen MP2PRT-PARTAH-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6f36e69e-1246-478d-ad1c-8dcaf4b8ba68.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARTAH-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/c8429043-4681-473c-b6d9-250accd3eb22

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 191; copy number 1: 1,822; copy number 2: 56,300; copy number 3: 83.

Homozygous deletions (total copy number 0; autosomes only): 191 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,861,886–89,078,784, 16 genes (within-gene range 0–1): IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14.
- chr2:89,968,867–89,990,221, 3 genes: IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:90,220,727–90,221,384, 1 gene: IGKV1D-8.
- chr7:38,239,580–38,340,998, 16 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr13:19,818,121–19,863,649, 3 genes: ST6GALNAC4P1, ZMYM5, AL355001.1.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–1): TRDD1, TRDD2.
- chr14:105,672,308–106,481,706, 126 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr14:106,564,375–106,579,236, 3 genes (within-gene range 0–1): IGHVII-49-1, IGHV3-50, IGHV5-51.
- chr14:106,584,718–106,606,551, 6 genes (within-gene range 0–1): IGHVII-51-2, IGHV3-52, IGHV3-53, IGHVII-53-1, IGHV3-54, IGHV4-55.
- chr14:106,680,603–106,791,233, 13 genes: IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,822. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
